TCGA case TCGA-KJ-A3U4 — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Corpus uteri; Tissue source site: University of Miami. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1a36d5de-a097-4323-90e9-f1b924a8a5d8

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (4)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 55.8 years (20,392 days); Year of diagnosis: 2012; Method of diagnosis: Surgical Resection; FIGO stage: Stage IA; FIGO staging edition year: 2009; Tumor grade: G1; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,095 days (3.0 years).
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 21.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 1.
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 11.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Days to treatment start: 1,033 days (2.8 years); Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded, whether given is unknown: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Breast, NOS; Laterality: Right; Classification of tumor: Prior primary; Age at diagnosis: 46.7 years (17,057 days); Days to diagnosis: -3,335 days (-9.1 years); AJCC staging edition: 6th.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin + Docetaxel + Tamoxifen + Trastuzumab; Days to treatment start: -3,296 days (-9.0 years); Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -3,195 days (-8.7 years); Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -3,100 days (-8.5 years); Treatment anatomic sites: Locoregional Site.
3. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Laterality: Left; Classification of tumor: Prior primary; Age at diagnosis: 50.2 years (18,352 days); Days to diagnosis: -2,040 days (-5.6 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin + Docetaxel; Days to treatment start: -2,016 days (-5.5 years); Treatment anatomic sites: Body, total.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -1,925 days (-5.3 years); Treatment anatomic sites: Breast.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -1,912 days (-5.2 years); Treatment anatomic sites: Locoregional Site.
4. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS), site: Abdomen, NOS. Age at diagnosis: 56.7 years (20,698 days); Days to diagnosis: 306 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 306 days; Residual disease: R0.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Days to follow up: 74 days; Disease response: Tumor Free.
- Day 306 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Abdomen, NOS; Days to recurrence: 306 days.
- Days to follow up: 1,095 days (3.0 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used; Hormonal replacement therapy status: No; Menopause status: Postmenopausal; Number of pregnancies: 2; Pregnancy outcome: Full Term Birth, NOS.
- Timepoint category: Initial Diagnosis; Weight: 96 kg; Height: 165 cm; BMI: 35.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KJ-A3U4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 420 mg.
  Slide TCGA-KJ-A3U4-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KJ-A3U4-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KJ-A3U4-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Serous endometrial adenocarcinoma; Method initial path diagnosis: Tumor resection; Surgical approach at diagnosis: open.
- Follow-up form: Lost to follow-up: No; History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; Hypertension diagnosis: No; Diabetes diagnosis indicator: No; Pregnancies full term count: 2; History colorectal cancer: No; Tumor status: Tumor free.
- Drug treatment: Pharmaceutical therapy drug name: letrozole femara.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Surgery: Other malignancy surgery type: radical mastectomy.
- Other malignancy form 1, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form 1, Drug treatment, Administered drug 2: Pharmaceutical therapy drug name: herceptin.
- Other malignancy form 1, Drug treatment, Administered drug 4: Pharmaceutical therapy drug name: taxotere.
- Other malignancy form 1, Radiation treatment: History radiation treatment to site of TCGA tumor: No.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Breast; Other malignancy histological type: infiltrating ductal carcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: modified radical mastectomy.

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Patient had a previous invasive ductal adenocarcinoma of the breast that was treated with locoregional radiation and systemic chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,095 days; disease-specific survival: no event (censored), 1,095 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 306 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-KJ-A3U4-01): tumor purity 0.76, ploidy 3.58, whole-genome doublings 1 (call status: snp_call).
